Somatic mutation profile of tumor specimen TCGA-CV-7416-01A (aliquot TCGA-CV-7416-01A-11D-2078-08) from TCGA case TCGA-CV-7416, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 29.9 years (10,936 days).
Specimen TCGA-CV-7416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d33a980-ae38-4d33-9f0a-0acc8a2d92ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7416-10A (Blood Derived Normal), aliquot TCGA-CV-7416-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2333ed25-fe20-4a98-9519-4bc832973368

The open-access MAF lists 74 somatic variants for this specimen: 50 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 22, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 33/54 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADA2 | c.904G>A p.A302T (on ENST00000262607; = p.A61T on NM_177405.3) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1333898789, COSV52830715; called by muse, mutect2, varscan2
- ADAM12 | c.1000G>T p.V334F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100901625; called by muse, mutect2, varscan2
- AUTS2 | c.2740G>A p.G914S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100719638; called by muse, mutect2, varscan2
- BRWD3 | c.2674A>T p.K892* | Nonsense Mutation (SNP) | VAF 17/505 reads (3%) | catalogued as COSV100956593; called by muse, mutect2
- BRWD3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 195/211 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs760487609, COSV100956595; called by muse, mutect2, varscan2
- CASZ1 | c.4601G>A p.R1534H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1299223191, COSV65457715; called by mutect2, varscan2
- CNTNAP4 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100273552, COSV56675847; called by muse, mutect2, varscan2
- COL17A1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs755190818, COSV100793386; called by muse, mutect2, varscan2
- COL4A4 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV100307821, COSV61630509; called by muse, mutect2, varscan2
- DBP | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99709666; called by muse, mutect2, varscan2
- DGKH | c.1559A>C p.K520T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99819660; called by muse, mutect2, varscan2
- FBH1 | c.977C>T p.A326V (on ENST00000362091 / NM_178150.3; = p.A377V on NM_032807.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs777764287, COSV100758962; called by muse, mutect2, varscan2
- FLNC | c.7678G>A p.V2560M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as COSV100368844; called by muse, mutect2, varscan2
- GNB1L | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770713977, COSV100284243, COSV61547626; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.781G>A p.G261S (on ENST00000354667 / NM_031243.3; = p.G249S on NM_002137.4) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs375157988; called by muse, mutect2, varscan2
- IGSF8 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); catalogued as rs761405117, COSV58757357; called by muse, mutect2, varscan2
- ITGA11 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs771813132, COSV100242266; called by muse, varscan2
- KANSL1L | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99911052; called by muse, mutect2, varscan2
- KMT2C | c.5764C>G p.P1922A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs753649191, COSV100077066; called by muse, mutect2, varscan2
- KPTN | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100583558; called by muse, mutect2, varscan2
- MARVELD2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs555314542, COSV57780249; called by muse, mutect2, varscan2
- MSH4 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99592636; called by muse, mutect2, varscan2
- MTSS2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100116720; called by muse, mutect2, varscan2
- MYH15 | c.5041G>T p.E1681* | Nonsense Mutation (SNP) | VAF 11/201 reads (5%) | catalogued as COSV56306235, COSV99844400; called by muse, mutect2
- NKD2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.117); catalogued as COSV99724441; called by muse, mutect2
- NRXN3 | c.829A>C p.M277L (on ENST00000557594 / NM_001272020.2; = p.M909L on NM_004796.6) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV99822216; called by muse, mutect2, varscan2
- OR51I1 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100972131; called by muse, varscan2
- OR8H3 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 75/394 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV57908210; called by muse, mutect2, varscan2
- OR9K2 | c.316G>T p.A106S (on ENST00000305377; = p.A84S on NM_001005243.1) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1309838943, COSV100543939; called by muse, mutect2, varscan2
- ORAI1 | c.864C>G p.H288Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.676); catalogued as COSV100345512; called by muse, mutect2, varscan2
- PFDN2 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV100919703; called by muse, mutect2, varscan2
- PGA5 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100409397; called by muse, mutect2, varscan2
- PLCD1 | c.1481A>G p.D494G | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99378646, COSV99379313; called by muse, mutect2, varscan2
- POU3F4 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100937344; called by muse, mutect2
- SEMA5B | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs772803361, COSV52095758; called by muse, mutect2, varscan2
- SLC22A7 | c.679G>C p.E227Q (on ENST00000372585 / NM_153320.2; = p.E225Q on NM_006672.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV101000874; called by muse, mutect2, varscan2
- TAOK1 | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99914842; called by muse, mutect2, varscan2
- TBR1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs1553510109, COSV101271501, COSV101271553; called by muse, mutect2, varscan2
- TEX13A | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100782106; called by muse, mutect2, varscan2
- UBR1 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313170537, COSV51930687; called by muse, mutect2, varscan2
- WDFY1 | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV99239927; called by muse, mutect2, varscan2
- WIPF1 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752911584, COSV99769554; called by muse, mutect2, varscan2
- ZFAND3 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99765879; called by muse, mutect2, varscan2
- CACNA2D4 | c.977_987del p.F326Yfs*5 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- MECOM | c.2208-3_2208-2dup p.X736_splice (on ENST00000468789 / NM_001105078.4; = p.X924_splice on NM_004991.4) | Splice Site (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- OR1D2 | c.325_335del p.A109Pfs*9 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- SAMHD1 | c.13_15dup p.D5dup | In Frame Ins (INS) | VAF 36/292 reads (12%) | called by mutect2, pindel, varscan2
- SHKBP1 | c.615_619del p.W205Cfs*48 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- TRMT5 | c.941_956del p.I314Kfs*24 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- CACNA2D2 | c.3261G>A p.Q1087= (on ENST00000479441 / NM_001174051.3; = p.Q1080= on NM_006030.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99818433; called by muse, mutect2, varscan2
- CCDC40 | c.3228G>A p.Q1076= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100163562; called by muse, mutect2, varscan2
- CNGB1 | c.822G>T p.G274= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51900612, COSV99212212; called by muse, varscan2
- CXCR2 | c.897C>T p.T299= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs13306439, COSV100579177, COSV59279855; called by muse, mutect2, varscan2
- GJA9 | c.424A>C p.R142= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV100668181; called by muse, mutect2, varscan2
- HTATIP2 | c.720C>G p.L240= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100424268; called by muse, varscan2
- HUWE1 | c.1320C>A p.T440= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99474442; called by muse, mutect2
- IGHG2 | c.717G>A p.K239= | Silent (SNP) | VAF 24/241 reads (10%) | called by muse, mutect2
- KIF19 | c.12C>T p.S4= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs781258084, COSV100739088; called by muse, mutect2, varscan2
- MAGEC1 | c.2103A>T p.G701= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99596658; called by muse, mutect2, varscan2
- MTTP | c.2658G>A p.P886= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs368664326; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1L1 | c.3094C>T p.L1032= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101006899; called by muse, mutect2, varscan2
- POLA1 | c.1533C>G p.V511= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100985818; called by muse, mutect2, varscan2
- POLR1A | c.2337C>T p.T779= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs762274332, COSV99808519; called by muse, mutect2, varscan2
- PPP2R1A | c.1173G>A p.V391= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100436507; called by muse, mutect2, varscan2
- RXFP3 | c.171G>A p.P57= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs769554354, COSV57507450; called by muse, mutect2
- RYR1 | c.2118C>T p.V706= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs769623563, COSV62103182; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM161A | c.1152C>T p.L384= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1472852246, COSV50777352, COSV50778535; called by muse, varscan2
- TMEM266 | c.1254G>A p.P418= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781444274, COSV101189665; called by muse, mutect2, varscan2
- ZNF329 | c.1545G>A p.Q515= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100798831; called by muse, mutect2, varscan2
- ZNF493 | c.1248C>A p.P416= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100828969; called by muse, mutect2, varscan2
- ZNF667 | c.1782G>T p.R594= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV99411034; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11597G>A | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs764658994, COSV99173571; called by muse, mutect2, varscan2
- KHK | c.210-301C>T | Intron (SNP) | VAF 20/75 reads (27%) | catalogued as rs762051940, COSV99566589; called by muse, mutect2, varscan2
